Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5532, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5532-01A (Primary Tumor).

The patient is a [REDACTED] with a history of PSA value of 11.4, 4 vessel bypass surgery in [REDACTED]. The patient also has a history of biopsy on [REDACTED], this biopsy reveals unilateral poorly differentiated prostatic adenocarcinoma of the right side.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical retropubic prostatectomy.

TCGA - EJ - 5532

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN THREE LYMPH NODES (0/3).

PART 2: LYMPH NODE, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN FIVE LYMPH NODES (0/5).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL RETROPUBIC PROSTATECTOMY -

- A. INVASIVE PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.0 CM.
- C. THE CARCINOMA INVOLVES 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA HAS ESTABLISHED EXTRACAPSULAR EXTENSION IN THE RIGHT ANTERIOR PROXIMAL URETHRAL MARGIN (SLIDE 3E), POSTERIOR RIGHT BASE (SLIDE 3X) AND ANTERIOR RIGHT MID (SLIDE 3N).
- E. ALTHOUGH ALL INKED SURGICAL MARGINS ARE NEGATIVE FOR TUMOR, A SMALL FOCUS OF PROSTATIC ADENOCARCINOMA IS IN CLOSE PROXIMITY TO THE RIGHT ANTERIOR PROXIMAL URETHRAL INKED MARGIN (LESS THAN 0.2 CM) (SLIDE 3E) (see comment).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a NO MX.
- K. TNM HISTOLOGIC GRADE = G3-4.

COMMENT:

Part 3: Several glands of invasive carcinoma with cautery artifact are present very close to the inked right anterior proximal urethral margin. Immunohistochemical stains were performed on slide 3E to highlight these glands; the stains include racemase (P504S), high molecular weight cytokeratin, p63, and PIN4 (a combination immunostain combining the aforementioned stains). The neoplastic glands show loss of basal cells and the cytoplasm is highlighted by racemase, confirming the glands as invasive prostatic carcinoma.

Overall, we interpret these findings as a negative surgical margin with the tumor close to the margin in an area of extracapsular extension of the tumor.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 11.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	40%
WEIGHT OF PROSTATE:	61.1 gmt
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	8
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 0926e2d7-fed7-4704-8225-d06cb045a036 (TCGA-EJ-5532.11AFAA3C-A99C-4E43-B4CB-EB139C9B1DAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).